Surgical pathology report (de-identified scan), TCGA case TCGA-S4-A8RP, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Chicago, specimen TCGA-S4-A8RP-01A (Primary Tumor).

[page 1 of 3]
Gender: Female

ICD-O-3
Adenocarcinoma duct NOS 8500/3
Site: ^{UCE}Pancreas head C25.0
^{path}Pancreas NOS C25.9
JW 3/12/14

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

Pancreaticoduodenectomy (Whipple):

- A. Portal lymph node:
- Reactive lymph node, no tumor (0/1)
- B. Common bile duct:
- Segment of bile duct, no tumor
- C. Pancreas and duodenum:
- Pancreatic ductal adenocarcinoma with invasion into duodenal wall and mucosa, see parameters
- Two of ten lymph nodes with metastatic adenocarcinoma (2/11)

PANCREAS (EXOCRINE): Resection

Tumor Size: 2.8 x 2 x 1.7 cm

Histologic Type: Ductal adenocarcinoma

Histologic Grade: G3: Poorly differentiated

Margins: All margins uninvolved by invasive carcinoma

Treatment Effect: Not applicable

Lympho-Vascular Invasion: Present

Perineural Invasion: Present

Pathologic Staging (pTNM): pT3, N1, MX

Primary Tumor (pT)

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

Regional Lymph Nodes (pN)

pN1: Regional lymph node metastasis

Specify: Number examined: 12

Number involved: 2

Distant Metastasis (pM)

Not applicable

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pancreas exocrine or the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xxx

[], M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] M.D.

Electronically Signed Out by [] M.D.

Clinical History:

The patient is a year old female with a history of duodenal mass undergoing Whipple procedure.

Specimens Received:

A: Portal lymph node

[page 2 of 3]
B: Common bile duct; biopsy
C: Pancreas duodenum

Gross Description:

The specimens are received in three containers labeled with the patient's name and medical record number.

A. The first container is additionally labeled "portal lymph node." It received fresh and placed in formalin is one ovoid tan-brown lymph node measuring 2.5 cm in greatest dimension. It is bisected and submitted in A1.

B. The second container is additionally labeled "common bile duct." Received fresh for intraoperative diagnosis is one piece of tissue measuring 1.3 x 1.3 x 0.4 cm. It is frozen and read as "hyperplastic changes, favor reactive" by Dr []. It is entirely submitted in B1 FS.

C. The third container is additionally labeled "duodenum." Received fresh and placed in formalin is a whipple specimen that consists of a 13.5 cm segment of duodenum with an internal circumference of 3-5 cm, and 6 x 5 x 3 cm portion of pancreas. The pancreatic neck margin is inked black and the uncinate margin is inked blue. The common bile duct is patent at the resection margin with a length of 1.5 cm and diameter of 0.8 cm. Serial sectioning of the pancreas reveals a 2.8 x 2 x 1.7 cm ill-defined, firm, stellate white-yellow mass. The mass is 2 cm from the pancreatic neck margin and uncinate margin. The mass does not grossly invade the pancreatic duct. It abuts the ampulla of Vater, is 0.5-0.7 cm from the duodenal serosa. The remaining pancreatic parenchyma is yellow-tan, rubbery and lobulated. The duodenum demonstrates grossly unremarkable, tan mucosa with a 0.3 cm wall thickness, which is focally up to 0.6 cm overlying the mass. The peripancreatic adipose tissue is dissected to reveal multiple pink-gray fibrofatty lymph nodes. Gross photographs are taken. Representative sections are submitted as follows:

C1	common bile duct margin
C2-3	uncinate margin
C4-5	peripancreatic fat
C6	neck margin
C7	proximal duodenal margin
C8	distal duodenal margin
C9-11	representative tumor and overlying duodenum
C12-13	ampulla
C14-C17	one lymph node, sectioned, each cassette
C18	5 lymph node candidates
C19-C22	additional adipose tissue

xxx

[], M.D.

Intraoperative Consult Diagnosis:

B1FS "hyperplastic changes, favor reactive" by Dr []

Source: NCI Genomic Data Commons file fcd776a5-7925-4653-b6b6-3a8273ea87f7 (TCGA-S4-A8RP.0E847270-2C5B-4C8E-BEAB-605FFDF518DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).